Somatic mutation profile of tumor specimen 0DOG3G from CCDI case PBCCEP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Epithelial-myoepithelial carcinoma; Tissue or organ of origin: Upper limb, NOS; Age at diagnosis: 3.0 years (1,109 days).
Specimen 0DOG3G: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2eb4009e-0c74-4914-9595-7ea38841592c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DOG2W (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/95fa024a-6072-47c3-b999-64ba1a76ecb2

The open-access MAF lists 3 somatic variants for this specimen: 1 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 2, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SLC35B2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 90/438 reads (21%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); called by muse, varscan2
- CFH | c.619+46A>T | Intron (SNP) | VAF 11/395 reads (3%) | called by muse, mutect2
- OR2J2 | c.-17-10C>G | Intron (SNP) | VAF 69/494 reads (14%) | called by muse, mutect2, varscan2
